Somatic mutation profile of tumor specimen MMRF_1242_1_BM_CD138pos (aliquot MMRF_1242_1_BM_CD138pos_T2_KHS5U_L15103) from MMRF case MMRF_1242, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.3 years (22,392 days).
Specimen MMRF_1242_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0439355-840f-4f82-b2e9-a6a9710ce328.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1242_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1242_1_PB_Whole_C1_KBS5U_L05353; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90e45b7c-8b2b-42fb-b02d-47f9b713a3d2

The open-access MAF lists 376 somatic variants for this specimen: 140 protein-altering or splice-affecting, 54 silent, 182 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, 3'UTR 85, Silent 54, Intron 49, 5'UTR 22, 3'Flank 11, 5'Flank 11, Nonsense Mutation 11, Splice Region 6, RNA 4, Splice Site 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC3 | c.3015G>C p.Q1005H | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773586959, COSV99558996; called by muse, mutect2, varscan2
- AGA | c.546C>A p.Y182* | Nonsense Mutation (SNP) | VAF 41/75 reads (55%) | catalogued as COSV52806258; called by muse, mutect2, varscan2
- AMFR | c.708-1G>A p.X236_splice | Splice Site (SNP) | VAF 25/93 reads (27%) | catalogued as COSV99315543; called by muse, mutect2, varscan2
- ASXL3 | c.5303G>A p.R1768K | Missense Mutation (SNP) | VAF 91/290 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV52456258; called by muse, mutect2, varscan2
- ATP6V1B2 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV52355377; called by muse, mutect2, varscan2
- CENPE | c.3703G>C p.E1235Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV54379091; called by muse, mutect2, varscan2
- CEP162 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57618459; called by muse, mutect2, varscan2
- COLQ | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs1428513924, COSV67525325; called by muse, mutect2, varscan2
- CPA1 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 504/977 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV50569686; called by muse, mutect2, varscan2
- CYP4V2 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 87/164 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs773125864, COSV66506483; called by muse, varscan2
- DEGS1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 148/341 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV60380341; called by muse, mutect2, varscan2
- DENND6B | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.348); catalogued as rs1362153693; called by muse, mutect2, varscan2
- DGKD | c.2276C>T p.T759M (on ENST00000264057 / NM_152879.3; = p.T715M on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/318 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs376456548, COSV51037705; called by muse, mutect2, varscan2
- DLGAP3 | c.2487C>T p.I829= | Splice Region (SNP) | VAF 59/118 reads (50%) | catalogued as COSV99332033; called by muse, mutect2, varscan2
- DPCD | c.64+2T>A p.X22_splice | Splice Site (SNP) | VAF 129/288 reads (45%) | catalogued as rs1184643720; called by muse, mutect2, varscan2
- EEF1B2 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 105/210 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99260978, COSV99261454; called by muse, mutect2, varscan2
- ENTHD1 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1300794317; called by muse, varscan2
- FGA | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as CM149603; called by muse, mutect2, varscan2
- GRAMD4 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV100730696; called by muse, mutect2
- H1-10 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs765023771, COSV100412921, COSV100412961; called by muse, mutect2, varscan2
- HBB | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as rs33961444, CM900431, CM993616; ClinVar: other; called by muse, mutect2, varscan2
- HEATR1 | c.5647G>A p.E1883K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV100857765; called by muse, mutect2, varscan2
- HERC2 | c.10963C>G p.L3655V | Missense Mutation (SNP) | VAF 100/221 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55354082; called by muse, mutect2, varscan2
- HS6ST1 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 128/282 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.765); catalogued as rs373944145; called by muse, varscan2
- IGHV2-70 | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs368831727; called by muse, varscan2
- IGHV4-34 | c.326G>C p.S109T | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs765275600; called by muse, mutect2, varscan2
- IGLV4-60 | c.329A>C p.D110A | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs368531437; called by muse, mutect2, varscan2
- IGLV6-57 | c.140G>A p.S47N | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs547493326; called by muse, varscan2
- INO80 | c.3817G>C p.E1273Q | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62738340; called by muse, mutect2, varscan2
- ITPRIP | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 184/365 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs1005019805; called by muse, mutect2, varscan2
- KCNJ9 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 60/307 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.858); catalogued as rs1421213922; called by muse, mutect2, varscan2
- KRT14 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 77/158 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as COSV51421312; called by muse, mutect2, varscan2
- KRTAP5-9 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 113/241 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.107); catalogued as COSV73200182, COSV73200258; called by muse, mutect2, varscan2
- MAP11 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1388160964; called by muse, mutect2, varscan2
- MAPKAP1 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV99785399; called by muse, mutect2, varscan2
- MBTPS1 | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1308858623; called by muse, varscan2
- MCAM | c.1646-4G>A | Splice Region (SNP) | VAF 295/658 reads (45%) | catalogued as rs754420255; called by muse, mutect2, varscan2
- MVB12A | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 184/373 reads (49%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.938); catalogued as rs200635108; called by muse, mutect2, varscan2
- NPDC1 | c.789-7del | Splice Region (DEL) | VAF 36/138 reads (26%) | catalogued as rs545374737; called by mutect2, varscan2
- NRCAM | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61030439, COSV61035172; called by muse, mutect2, varscan2
- NUDT10 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 130/165 reads (79%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV62854902; called by muse, varscan2
- NUP98 | c.4537C>T p.R1513* (on ENST00000359171 / NM_001365126.1; = p.R1496* on NM_016320.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 29/54 reads (54%) | catalogued as COSV61433047; called by muse, mutect2, varscan2
- OR5H2 | c.407T>G p.L136R | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs753718120; called by muse, mutect2
- P4HA2 | c.620C>G p.S207* | Nonsense Mutation (SNP) | VAF 93/155 reads (60%) | catalogued as COSV51326357; called by muse, mutect2, varscan2
- PABPC3 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs757885062, COSV55799889; called by muse, varscan2
- PCYOX1 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs748813203; called by muse, mutect2, varscan2
- PEX11B | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 201/443 reads (45%) | catalogued as rs781924210, COSV57161932; called by muse, mutect2, varscan2
- PFKP | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 188/387 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); catalogued as rs150500285, COSV66899580; called by muse, mutect2, varscan2
- PHKB | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.241); catalogued as COSV100069041; called by muse, mutect2
- PLOD1 | c.1875G>C p.E625D | Missense Mutation (SNP) | VAF 157/370 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.157); catalogued as COSV52147508; called by muse, mutect2, varscan2
- POLG2 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 295/580 reads (51%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs782676579; called by muse, mutect2, varscan2
- PTAR1 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.47); catalogued as rs746920322; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 198/390 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- SAMHD1 | c.209-1G>C p.X70_splice | Splice Site (SNP) | VAF 30/63 reads (48%) | catalogued as COSV53429928, COSV53431660; called by muse, mutect2, varscan2
- SCAMP3 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 194/383 reads (51%) | catalogued as rs1355670993; called by muse, mutect2, varscan2
- SHANK3 | c.4898C>T p.S1633L | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.519); catalogued as COSV53188172; called by muse, varscan2
- SLC35G5 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs370522572; called by muse, mutect2, varscan2
- SMAD1 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1260108423; called by muse, mutect2, varscan2
- SSC5D | c.3358G>A p.E1120K | Missense Mutation (SNP) | VAF 16/572 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.108); catalogued as rs981087317; called by muse, mutect2
- TENM3 | c.631A>G p.R211G | Missense Mutation (SNP) | VAF 110/276 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.239); catalogued as rs923678656; called by muse, mutect2, varscan2
- TGOLN2 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 146/304 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV56405209; called by muse, mutect2, varscan2
- UBR4 | c.5238G>C p.Q1746H | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0.259); catalogued as COSV64384047; called by muse, mutect2, varscan2
- USP15 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1565792734; called by muse, mutect2, varscan2
- USP7 | c.2270T>C p.L757P | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.713); catalogued as COSV61217270; called by muse, mutect2
- VGLL3 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1329036237; called by muse, mutect2, varscan2
- ZNF548 | c.807G>C p.M269I | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1168290719; called by muse, mutect2, varscan2
- AC092143.1 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 56/62 reads (90%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- ADRB1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARF5 | c.70G>C p.G24R | Missense Mutation (SNP) | VAF 191/431 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATCAY | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- BTBD16 | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- C2CD2 | c.389G>A p.C130Y | Missense Mutation (SNP) | VAF 162/238 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- CABIN1 | c.4259G>T p.G1420V | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CADPS2 | c.726G>A p.M242I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CD82 | c.-102-3C>A | Splice Region (SNP) | VAF 105/239 reads (44%) | called by muse, mutect2, varscan2
- CDC73 | c.69C>G p.D23E | Missense Mutation (SNP) | VAF 313/700 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDK17 | c.595G>C p.G199R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CEP152 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- COL5A3 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CPEB2 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 49/103 reads (48%) | called by muse, mutect2, varscan2
- DGKH | c.928C>G p.P310A | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- DIS3 | c.736T>G p.Y246D | Missense Mutation (SNP) | VAF 50/59 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- DMXL2 | c.4030C>G p.L1344V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DUSP7 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 149/318 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- FAM160A2 | c.2038G>T p.E680* (on ENST00000449352 / NM_001098794.2; = p.E694* on NM_032127.4) | Nonsense Mutation (SNP) | VAF 317/642 reads (49%) | called by muse, mutect2, varscan2
- FOXF1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 322/338 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- FOXK1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FUT2 | c.106C>G p.Q36E | Missense Mutation (SNP) | VAF 254/553 reads (46%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- GNG5 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- GON4L | c.-26-3C>G | Splice Region (SNP) | VAF 319/702 reads (45%) | called by muse, mutect2, varscan2
- HEATR9 | c.1362G>C p.K454N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IGLV3-1 | c.37T>G p.Y13D | Missense Mutation (SNP) | VAF 212/226 reads (94%) | SIFT tolerated (0.19); PolyPhen benign (0.147); called by muse, varscan2
- JAK2 | c.244C>A p.H82N | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- KDM6B | c.2866G>C p.A956P | Missense Mutation (SNP) | VAF 96/208 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- LMTK3 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 126/257 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- LTA | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 142/313 reads (45%) | SIFT tolerated (0.79); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MUC5AC | c.13118C>T p.P4373L | Missense Mutation (SNP) | VAF 213/628 reads (34%) | SIFT tolerated (0.06); called by muse, mutect2, varscan2
- MX2 | c.1986G>C p.Q662H | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYL12A | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 88/290 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO10 | c.2426G>A p.R809K | Missense Mutation (SNP) | VAF 188/403 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPIPB2 | c.991G>A p.E331K (on ENST00000399147; = p.E191K on NM_001355514.1) | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NUDC | c.690G>C p.E230D | Missense Mutation (SNP) | VAF 122/234 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, varscan2
- NUS1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5D13 | c.245A>C p.K82T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- PALM3 | c.88G>A p.E30K (on ENST00000340790; = p.E45K on NM_001145028.2) | Missense Mutation (SNP) | VAF 124/203 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PELP1 | c.2851G>A p.E951K | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PHACTR2 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PIK3C2A | c.5012G>A p.S1671N | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PIK3C3 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- PIPOX | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLA2G15 | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, varscan2
- PLA2G15 | c.403+5G>T | Splice Region (SNP) | VAF 32/65 reads (49%) | called by muse, varscan2
- PLEKHG1 | c.1187T>C p.V396A | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- POU4F1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 191/204 reads (94%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PPP4R4 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 104/222 reads (47%) | called by muse, mutect2, varscan2
- RALGAPA1 | c.2090del p.K697Sfs*34 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2
- RRH | c.419C>G p.T140S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RUFY4 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 165/368 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- RYR1 | c.12682G>C p.E4228Q | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SAMHD1 | c.1004T>G p.I335S | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- SBNO1 | c.3549G>C p.E1183D (on ENST00000420886; = p.E1182D on NM_018183.5) | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SEC23A | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 89/214 reads (42%) | called by muse, mutect2, varscan2
- SH3BP1 | c.131G>C p.R44P | Missense Mutation (SNP) | VAF 140/277 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- SHKBP1 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SLC26A8 | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- SLIT2 | c.2752A>T p.K918* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- SMYD1 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT tolerated (0.25); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SNX29 | c.28del p.R10Dfs*12 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel
- TFRC | c.1058G>C p.C353S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM131L | c.3297C>G p.F1099L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM214 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 116/275 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.104); called by muse, mutect2
- USH1C | c.987G>C p.K329N | Missense Mutation (SNP) | VAF 107/239 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- USP15 | c.2290G>A p.E764K (on ENST00000280377 / NM_001351159.2; = p.E735K on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- USP5 | c.1540G>C p.E514Q | Missense Mutation (SNP) | VAF 85/189 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- USP7 | c.836dup p.L279Ffs*12 | Frame Shift Ins (INS) | VAF 5/18 reads (28%) | called by mutect2, pindel, varscan2
- VSX1 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.142); called by muse, mutect2
- YTHDC1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ZFHX3 | c.2274G>C p.Q758H | Missense Mutation (SNP) | VAF 172/187 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF385D | c.371A>C p.K124T | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- ZNF564 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 145/348 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS5 | c.57G>T p.A19= | Silent (SNP) | VAF 50/189 reads (26%) | catalogued as rs987006846; called by muse, mutect2, varscan2
- ADPGK | c.969G>C p.L323= | Silent (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- ANKRD63 | c.153C>G p.L51= | Silent (SNP) | VAF 81/186 reads (44%) | called by muse, mutect2, varscan2
- ATRN | c.318C>T p.V106= | Silent (SNP) | VAF 74/172 reads (43%) | called by muse, varscan2
- BTBD19 | c.348G>A p.L116= | Silent (SNP) | VAF 56/98 reads (57%) | called by muse, mutect2, varscan2
- CATSPER1 | c.942C>G p.L314= | Silent (SNP) | VAF 224/486 reads (46%) | catalogued as COSV56413503; called by muse, mutect2, varscan2
- CD83 | c.105C>T p.C35= | Silent (SNP) | VAF 187/355 reads (53%) | catalogued as rs1048445037; called by muse, mutect2, varscan2
- CDON | c.3456C>T p.L1152= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as rs773182905; called by muse, mutect2, varscan2
- CLDN7 | c.162C>T p.C54= | Silent (SNP) | VAF 356/764 reads (47%) | called by muse, mutect2, varscan2
- DCUN1D3 | c.762C>A p.G254= | Silent (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- DHX57 | c.1950G>C p.L650= | Silent (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- DIP2A | c.2589G>A p.P863= | Silent (SNP) | VAF 173/559 reads (31%) | catalogued as rs775298807, COSV59480934; called by muse, mutect2, varscan2
- DISP2 | c.1863C>T p.F621= | Silent (SNP) | VAF 87/182 reads (48%) | called by muse, mutect2, varscan2
- DNMBP | c.2931C>T p.Y977= | Silent (SNP) | VAF 49/121 reads (40%) | catalogued as rs746369495; called by muse, mutect2, varscan2
- DOK4 | c.363G>A p.L121= | Silent (SNP) | VAF 60/171 reads (35%) | called by muse, mutect2, varscan2
- DRC1 | c.129C>T p.I43= | Silent (SNP) | VAF 74/159 reads (47%) | called by muse, mutect2, varscan2
- EFR3B | c.2118G>C p.S706= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as rs775848123; called by muse, mutect2, varscan2
- ELMO3 | c.1191C>T p.F397= (on ENST00000652269; = p.F344= on NM_024712.5) | Silent (SNP) | VAF 198/590 reads (34%) | called by muse, mutect2, varscan2
- FBRS | c.1275C>G p.L425= (on ENST00000287468; = p.L945= on NM_001105079.3) | Silent (SNP) | VAF 327/672 reads (49%) | catalogued as COSV54917961; called by muse, mutect2, varscan2
- FBXL15 | c.876C>T p.F292= | Silent (SNP) | VAF 88/193 reads (46%) | catalogued as COSV50065610; called by muse, mutect2, varscan2
- GTF2IRD2B | c.288G>A p.G96= | Silent (SNP) | VAF 34/89 reads (38%) | called by muse, varscan2
- HSD17B2 | c.150C>T p.L50= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs377625310; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.105C>G p.A35= | Silent (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- KCNAB2 | c.1047C>T p.H349= | Silent (SNP) | VAF 301/739 reads (41%) | catalogued as rs758209251, COSV99315226; called by muse, mutect2
- KDM1A | c.348G>A p.A116= | Silent (SNP) | VAF 178/328 reads (54%) | catalogued as rs748649267; called by muse, mutect2, varscan2
- MRGPRF | c.918C>G p.L306= | Silent (SNP) | VAF 148/343 reads (43%) | called by muse, mutect2, varscan2
- MTO1 | c.111C>T p.F37= | Silent (SNP) | VAF 275/597 reads (46%) | catalogued as rs375783962; called by muse, mutect2, varscan2
- MYO1D | c.741C>T p.F247= | Silent (SNP) | VAF 45/88 reads (51%) | catalogued as rs1316220524; called by muse, mutect2, varscan2
- NPAS4 | c.1950C>T p.F650= | Silent (SNP) | VAF 148/336 reads (44%) | catalogued as rs754106311; called by muse, varscan2
- NUP214 | c.3348G>A p.L1116= | Silent (SNP) | VAF 56/92 reads (61%) | called by muse, mutect2, varscan2
- OBSCN | c.21954C>G p.L7318= | Silent (SNP) | VAF 593/1232 reads (48%) | called by muse, mutect2, varscan2
- OR2T10 | c.198C>T p.L66= | Silent (SNP) | VAF 75/296 reads (25%) | catalogued as COSV57897028; called by muse, mutect2, varscan2
- PCBP1 | c.936G>A p.Q312= | Silent (SNP) | VAF 95/208 reads (46%) | catalogued as rs1346732223; called by muse, mutect2, varscan2
- PCSK2 | c.1767G>A p.L589= | Silent (SNP) | VAF 43/85 reads (51%) | catalogued as COSV52741784; called by muse, mutect2, varscan2
- PGAP1 | c.24C>T p.L8= | Silent (SNP) | VAF 174/324 reads (54%) | called by muse, varscan2
- PHKA1 | c.1386G>A p.V462= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as COSV59808326; called by muse, mutect2, varscan2
- PIK3CA | c.861G>A p.L287= | Silent (SNP) | VAF 16/315 reads (5%) | catalogued as COSV55877168; called by muse, mutect2
- RHBDL3 | c.489C>T p.P163= | Silent (SNP) | VAF 55/105 reads (52%) | called by muse, mutect2, varscan2
- RP1L1 | c.4212C>T p.S1404= | Silent (SNP) | VAF 66/850 reads (8%) | catalogued as rs745543982, COSV66759828; called by muse, mutect2
- RPS15A | c.363A>G p.T121= | Silent (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- RTL5 | c.571C>T p.L191= | Silent (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- RYR1 | c.84C>T p.L28= | Silent (SNP) | VAF 49/92 reads (53%) | catalogued as rs781676755; called by muse, mutect2, varscan2
- SLC16A3 | c.1188C>T p.L396= | Silent (SNP) | VAF 92/186 reads (49%) | catalogued as rs762495427, COSV58364423; called by muse, varscan2
- SLC25A20 | c.102C>T p.V34= | Silent (SNP) | VAF 42/91 reads (46%) | called by muse, mutect2, varscan2
- SLC9C2 | c.2965C>T p.L989= | Silent (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- SOWAHC | c.1173G>A p.K391= | Silent (SNP) | VAF 179/388 reads (46%) | catalogued as rs763086173; called by muse, mutect2, varscan2
- SSB | c.820C>T p.L274= | Silent (SNP) | VAF 43/44 reads (98%) | catalogued as COSV53625803; called by muse, mutect2, varscan2
- TECTA | c.5988C>A p.I1996= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- TEFM | c.567G>A p.L189= | Silent (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- TRAK1 | c.1497G>C p.L499= (on ENST00000327628 / NM_001349247.2; = p.L441= on NM_014965.5) | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV58263065; called by muse, mutect2, varscan2
- UNC13C | c.3807G>A p.E1269= | Silent (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- VWA7 | c.52C>T p.L18= | Silent (SNP) | VAF 65/140 reads (46%) | called by muse, mutect2, varscan2
- XIRP1 | c.5010A>C p.P1670= | Silent (SNP) | VAF 285/602 reads (47%) | catalogued as COSV61141003; called by muse, mutect2, varscan2
- ZNF692 | c.981G>A p.L327= | Silent (SNP) | VAF 116/275 reads (42%) | called by muse, mutect2, varscan2
- ABCC5 | c.591+1999G>C | Intron (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- ADGRD2 | c.2026+66A>C | Intron (SNP) | VAF 9/221 reads (4%) | called by muse, mutect2
- ADGRG5 | c.*1201C>G | 3'UTR (SNP) | VAF 109/268 reads (41%) | called by muse, mutect2, varscan2
- ADORA2A | c.*126G>A | 3'UTR (SNP) | VAF 119/259 reads (46%) | called by muse, mutect2, varscan2
- AFAP1 | c.2001+51G>C | Intron (SNP) | VAF 13/25 reads (52%) | catalogued as COSV100631134; called by muse, varscan2
- AGPAT2 | c.*122C>G | 3'UTR (SNP) | VAF 82/277 reads (30%) | called by muse, mutect2, varscan2
- AL138831.3 | n.680C>T | RNA (SNP) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- AL138930.1 | n.115+4423G>C | Intron (SNP) | VAF 20/67 reads (30%) | catalogued as rs954344938; called by muse, mutect2, varscan2
- AL161729.4 | chr9:95516672 C>T | 3'Flank (SNP) | VAF 206/721 reads (29%) | called by mutect2, varscan2
- AMPD2 | chr1:109619885 C>T | 5'Flank (SNP) | VAF 119/247 reads (48%) | called by muse, mutect2, varscan2
- ANKRD42 | chr11:83193769 G>A | 5'Flank (SNP) | VAF 35/427 reads (8%) | called by muse, mutect2
- ANKRD53 | chr2:70978512 G>A | 5'Flank (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505609 C>G | 5'Flank (SNP) | VAF 102/219 reads (47%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500042 C>G | 5'Flank (SNP) | VAF 82/184 reads (45%) | called by muse, varscan2
- AP000769.5 | chr11:65500053 G>C | 5'Flank (SNP) | VAF 95/200 reads (48%) | called by muse, varscan2
- APAF1 | c.*1879C>G | 3'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- APOBEC3B | c.*84A>G | 3'UTR (SNP) | VAF 263/716 reads (37%) | called by muse, mutect2, varscan2
- ARMC9 | c.2261+1893G>C | Intron (SNP) | VAF 54/121 reads (45%) | called by muse, mutect2, varscan2
- ARNT2 | c.*430C>T | 3'UTR (SNP) | VAF 93/201 reads (46%) | called by muse, mutect2, varscan2
- ATP2B2 | chr3:10324809 A>T | 3'Flank (SNP) | VAF 55/123 reads (45%) | called by muse, varscan2
- ATP2B2 | chr3:10324845 C>G | 3'Flank (SNP) | VAF 64/140 reads (46%) | called by muse, varscan2
- BDKRB2 | c.-110G>A | 5'UTR (SNP) | VAF 36/94 reads (38%) | catalogued as rs760295240; called by muse, varscan2
- BHLHE23 | c.*59C>G | 3'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- BMP5 | c.*482C>T | 3'UTR (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- BRWD1 | c.6572-3233G>A | Intron (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- BTD | c.-318C>G | 5'UTR (SNP) | VAF 92/186 reads (49%) | catalogued as rs763364838, COSV57728683; called by muse, mutect2
- C16orf95 | c.*211C>T | 3'UTR (SNP) | VAF 22/23 reads (96%) | called by muse, mutect2, varscan2
- C19orf47 | c.78+67G>A | Intron (SNP) | VAF 19/48 reads (40%) | catalogued as rs1042139906; called by muse, mutect2, varscan2
- CCDC74A | chr2:131527776 T>C | 5'Flank (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- CEP170 | c.3677-278C>T | Intron (SNP) | VAF 192/382 reads (50%) | catalogued as rs3015131; called by muse, mutect2, varscan2
- CFAP157 | c.*1478G>C | 3'UTR (SNP) | VAF 36/626 reads (6%) | catalogued as rs1209363713; called by muse, mutect2
- CHMP6 | c.-55G>A | 5'UTR (SNP) | VAF 88/195 reads (45%) | catalogued as COSV100289546; called by muse, mutect2, varscan2
- CMPK1 | c.*331A>T | 3'UTR (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- CPEB4 | c.-1036T>C | 5'UTR (SNP) | VAF 41/103 reads (40%) | called by muse, mutect2, varscan2
- DCAF10 | c.*971G>C | 3'UTR (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- DEF8 | c.*1987C>T | 3'UTR (SNP) | VAF 75/82 reads (91%) | called by muse, varscan2
- DEF8 | c.*2070C>T | 3'UTR (SNP) | VAF 78/85 reads (92%) | called by muse, mutect2, varscan2
- DHRS13 | c.*651G>C | 3'UTR (SNP) | VAF 104/203 reads (51%) | called by muse, mutect2, varscan2
- DHX57 | c.1905+47del | Intron (DEL) | VAF 18/39 reads (46%) | called by mutect2, pindel, varscan2
- DIO2 | c.*3000C>T | 3'UTR (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- DIPK1C | c.*235C>A | 3'UTR (SNP) | VAF 67/131 reads (51%) | called by muse, mutect2, varscan2
- DLG4 | c.787+142G>C | Intron (SNP) | VAF 180/365 reads (49%) | called by muse, mutect2, varscan2
- DTNA | c.1662+3054A>G | Intron (SNP) | VAF 142/222 reads (64%) | called by muse, mutect2, varscan2
- DZIP3 | c.*6+325C>T | Intron (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- EAF1 | c.-30C>G | 5'UTR (SNP) | VAF 71/164 reads (43%) | called by muse, mutect2, varscan2
- EFEMP2 | c.847+29G>T | Intron (SNP) | VAF 163/350 reads (47%) | called by muse, mutect2, varscan2
- EHF | c.-3-10086C>G | Intron (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- EIF3F | chr11:7997745 G>A | 3'Flank (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- EIF4EBP2 | c.*5699C>G | 3'UTR (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2, varscan2
- ELK3 | c.*1377C>G | 3'UTR (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- ELL2 | c.1761+94G>C | Intron (SNP) | VAF 37/75 reads (49%) | catalogued as rs1463389226; called by muse, mutect2, varscan2
- EPS15 | c.*1263G>A | 3'UTR (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- FAM169A | c.*3579C>T | 3'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- FBXL2 | c.455+46G>A | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2
- FBXO21 | chr12:117143827 C>G | 3'Flank (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- FKBP15 | c.*2106A>G | 3'UTR (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-1501C>T | Intron (SNP) | VAF 62/116 reads (53%) | catalogued as rs1029809265, COSV57929429; called by muse, mutect2, varscan2
- FMN1 | c.2044-1772C>G | Intron (SNP) | VAF 36/81 reads (44%) | catalogued as COSV57919430; called by muse, mutect2, varscan2
- FOSL2 | c.*3860C>T | 3'UTR (SNP) | VAF 44/86 reads (51%) | called by muse, varscan2
- FOXK2 | c.*62C>T | 3'UTR (SNP) | VAF 189/413 reads (46%) | catalogued as rs978845373; called by muse, mutect2, varscan2
- FOXN3 | chr14:89159943 C>A | 3'Flank (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2, varscan2
- GIPC2 | c.*2459C>G | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- GLP2R | c.1057-4159C>T | Intron (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- GPATCH2 | c.*1786G>C | 3'UTR (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- GPBAR1 | c.*31C>T | 3'UTR (SNP) | VAF 193/465 reads (42%) | called by muse, mutect2, varscan2
- GTF2A1 | c.*464A>C | 3'UTR (SNP) | VAF 11/32 reads (34%) | called by muse, varscan2
- GTF2A1 | c.*350A>C | 3'UTR (SNP) | VAF 16/36 reads (44%) | called by muse, varscan2
- HDAC6 | c.-30-117G>C | Intron (SNP) | VAF 89/94 reads (95%) | called by muse, mutect2, varscan2
- HIKESHI | c.540-199C>G | Intron (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- HINFP | c.-10-2201G>T | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- HOXA13 | c.*1210_*1211dup | 3'UTR (INS) | VAF 28/76 reads (37%) | called by mutect2, pindel, varscan2
- HS3ST3B1 | c.*1331G>A | 3'UTR (SNP) | VAF 55/111 reads (50%) | called by muse, mutect2, varscan2
- IL16 | chr15:81309917 G>A | 3'Flank (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- INPP1 | c.467-70G>C | Intron (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- ITSN2 | c.*718C>G | 3'UTR (SNP) | VAF 12/38 reads (32%) | called by muse, varscan2
- ITSN2 | c.*638T>C | 3'UTR (SNP) | VAF 32/68 reads (47%) | called by muse, varscan2
- ITSN2 | c.*446G>T | 3'UTR (SNP) | VAF 74/172 reads (43%) | called by muse, mutect2, varscan2
- IYD | c.*4689C>T | 3'UTR (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2
- JAML | c.773-53C>T | Intron (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- KCMF1 | c.*1065G>T | 3'UTR (SNP) | VAF 13/29 reads (45%) | catalogued as rs1018236572, COSV69054472; called by muse, mutect2, varscan2
- KCNK3 | c.*4477C>G | 3'UTR (SNP) | VAF 59/122 reads (48%) | called by muse, mutect2, varscan2
- KIF9 | c.-6+1494G>A | Intron (SNP) | VAF 195/386 reads (51%) | called by muse, mutect2, varscan2
- LCLAT1 | c.743-34072C>T | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as rs779489513, COSV58371106; called by muse, mutect2, varscan2
- LEF1 | c.-221G>A | 5'UTR (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- LRIG3 | c.-121G>A | 5'UTR (SNP) | VAF 69/140 reads (49%) | catalogued as rs544003001; called by muse, mutect2, varscan2
- LRP1B | chr2:142131500 A>G | 5'Flank (SNP) | VAF 62/142 reads (44%) | called by muse, mutect2, varscan2
- MACF1 | c.220+21267G>C | Intron (SNP) | VAF 136/349 reads (39%) | catalogued as rs1426064582; called by muse, mutect2, varscan2
- MAGI3 | c.*795C>T | 3'UTR (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- MAZ | c.*715G>C | 3'UTR (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- MED1 | c.*2433C>G | 3'UTR (SNP) | VAF 55/138 reads (40%) | called by muse, varscan2
- METTL15 | c.*1219C>G | 3'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- MIR6511A3 | chr16:16366683 C>T | 5'Flank (SNP) | VAF 14/79 reads (18%) | catalogued as rs1449319661; called by muse, mutect2, varscan2
- MPZL1 | c.-116C>T | 5'UTR (SNP) | VAF 32/149 reads (21%) | called by muse, mutect2, varscan2
- MTG1 | c.511+72C>G | Intron (SNP) | VAF 140/285 reads (49%) | called by muse, mutect2, varscan2
- MYOZ2 | c.*246C>T | 3'UTR (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442540 C>G | 3'Flank (SNP) | VAF 91/92 reads (99%) | called by muse, mutect2, varscan2
- N4BP3 | c.*2109C>G | 3'UTR (SNP) | VAF 21/688 reads (3%) | called by muse, mutect2
- NAV2 | chr11:19713244 C>T | 5'Flank (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- NCR1 | c.71-52A>C | Intron (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- NFS1 | c.408+1682G>C | Intron (SNP) | VAF 6/8 reads (75%) | called by muse, mutect2, varscan2
- NFYC | c.720+346G>A | Intron (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- NKAIN1 | c.*138G>C | 3'UTR (SNP) | VAF 43/82 reads (52%) | called by muse, mutect2, varscan2
- OSGEP | c.236-13T>A | Intron (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- PARP1 | c.-66G>A | 5'UTR (SNP) | VAF 180/666 reads (27%) | catalogued as COSV100828518; called by muse, mutect2, varscan2
- PDE6D | c.*420C>T | 3'UTR (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- PLA2G15 | c.285-111G>A | Intron (SNP) | VAF 22/46 reads (48%) | called by muse, varscan2
- PRKACB | c.-206C>T | 5'UTR (SNP) | VAF 7/108 reads (6%) | catalogued as rs1557887994, COSV65771414; called by muse, mutect2
- PRMT8 | c.*561C>T | 3'UTR (SNP) | VAF 7/64 reads (11%) | catalogued as rs964524603; called by muse, mutect2
- PRRT1 | c.559-44G>A | Intron (SNP) | VAF 40/75 reads (53%) | called by muse, mutect2, varscan2
- PTBP2 | c.-21G>A | 5'UTR (SNP) | VAF 319/644 reads (50%) | catalogued as rs766539552, COSV64624579; called by muse, mutect2, varscan2
- PTGDR2 | c.*84C>T | 3'UTR (SNP) | VAF 48/108 reads (44%) | catalogued as rs756614528; called by muse, mutect2, varscan2
- PTPRVP | n.4287G>C | RNA (SNP) | VAF 96/209 reads (46%) | called by muse, mutect2
- RAB27B | c.*5467G>A | 3'UTR (SNP) | VAF 16/26 reads (62%) | called by muse, mutect2, varscan2
- RAB4B | c.-5G>A | 5'UTR (SNP) | VAF 136/275 reads (49%) | catalogued as rs186067642; called by muse, mutect2, varscan2
- RAP2A | c.-212C>T | 5'UTR (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2
- RARRES2 | c.-21+191C>T | Intron (SNP) | VAF 428/878 reads (49%) | called by muse, mutect2, varscan2
- RASD2 | c.*1666G>A | 3'UTR (SNP) | VAF 138/282 reads (49%) | called by muse, mutect2, varscan2
- RBFOX1 | chr16:7711936 C>T | 3'Flank (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- RESF1 | c.*160G>C | 3'UTR (SNP) | VAF 55/124 reads (44%) | called by muse, mutect2, varscan2
- RGMB | c.-378C>T | 5'UTR (SNP) | VAF 91/201 reads (45%) | catalogued as rs1324627968; called by muse, mutect2, varscan2
- RMI2 | c.*435G>A | 3'UTR (SNP) | VAF 39/99 reads (39%) | called by muse, mutect2, varscan2
- RNASEH2C | c.*421G>C | 3'UTR (SNP) | VAF 53/130 reads (41%) | called by muse, mutect2, varscan2
- RNF152 | c.*7632G>T | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- RNF169 | c.*3164C>T | 3'UTR (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2
- RPH3AL | c.-37+1879A>G | Intron (SNP) | VAF 75/141 reads (53%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.174+13318G>A | Intron (SNP) | VAF 405/873 reads (46%) | called by muse, mutect2, varscan2
- RSPRY1 | c.*269G>A | 3'UTR (SNP) | VAF 60/94 reads (64%) | called by muse, mutect2, varscan2
- RSPRY1 | c.*483G>A | 3'UTR (SNP) | VAF 46/67 reads (69%) | called by muse, varscan2
- RSPRY1 | c.*553G>A | 3'UTR (SNP) | VAF 24/32 reads (75%) | called by muse, varscan2
- RSPRY1 | c.*778G>A | 3'UTR (SNP) | VAF 18/40 reads (45%) | called by muse, varscan2
- RSPRY1 | c.*779G>A | 3'UTR (SNP) | VAF 17/39 reads (44%) | called by muse, varscan2
- RSPRY1 | c.*824G>A | 3'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, varscan2
- SDHAP1 | n.1361G>A | RNA (SNP) | VAF 104/378 reads (28%) | catalogued as rs1346245568; called by muse, varscan2
- SEC14L2 | c.-66G>A | 5'UTR (SNP) | VAF 125/283 reads (44%) | called by muse, mutect2, varscan2
- SEC22C | c.*4142G>A | 3'UTR (SNP) | VAF 38/88 reads (43%) | called by muse, varscan2
- SEMA5A | c.*7179C>T | 3'UTR (SNP) | VAF 5/9 reads (56%) | called by muse, varscan2
- SEPTIN9 | c.722-36237C>T | Intron (SNP) | VAF 149/316 reads (47%) | called by muse, mutect2, varscan2
- SERBP1 | chr1:67408196 G>C | 3'Flank (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2
- SET | c.113-1604G>C | Intron (SNP) | VAF 51/135 reads (38%) | catalogued as rs1397486355; called by muse, mutect2, varscan2
- SHTN1 | c.*4585G>A | 3'UTR (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- SLC35F4 | c.-60C>T | 5'UTR (SNP) | VAF 38/80 reads (48%) | called by muse, mutect2, varscan2
- SMARCC1 | c.*594G>A | 3'UTR (SNP) | VAF 68/183 reads (37%) | called by muse, mutect2, varscan2
- SMPD3 | c.1867-124G>A | Intron (SNP) | VAF 8/62 reads (13%) | called by muse, varscan2
- SMPD3 | c.1866+83G>A | Intron (SNP) | VAF 50/109 reads (46%) | catalogued as rs1166919897; called by muse, varscan2
- SMPD3 | c.1866+42G>A | Intron (SNP) | VAF 80/174 reads (46%) | catalogued as rs934239057; called by muse, varscan2
- SNRPEP2 | n.279G>C | RNA (SNP) | VAF 11/29 reads (38%) | catalogued as rs772595853; called by muse, mutect2, varscan2
- SOX13 | c.*405C>T | 3'UTR (SNP) | VAF 370/794 reads (47%) | called by muse, mutect2, varscan2
- SP140 | c.-29C>G | 5'UTR (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- SP2 | c.*845C>G | 3'UTR (SNP) | VAF 62/127 reads (49%) | called by muse, mutect2, varscan2
- SREBF1 | c.*159G>A | 3'UTR (SNP) | VAF 77/147 reads (52%) | called by muse, mutect2, varscan2
- SREBF2 | c.*558C>A | 3'UTR (SNP) | VAF 63/119 reads (53%) | called by muse, mutect2, varscan2
- SS18L1 | c.*312C>G | 3'UTR (SNP) | VAF 151/347 reads (44%) | called by muse, mutect2, varscan2
- STIP1 | chr11:64185654 C>T | 5'Flank (SNP) | VAF 86/175 reads (49%) | called by muse, mutect2
- STK10 | c.*2759dup | 3'UTR (INS) | VAF 27/67 reads (40%) | called by mutect2, pindel, varscan2
- STK32A | c.*1642G>A | 3'UTR (SNP) | VAF 4/10 reads (40%) | catalogued as rs1407022877; called by muse, mutect2, varscan2
- STRBP | c.*3493C>G | 3'UTR (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- SULT1C2 | c.*134G>A | 3'UTR (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- SVIP | c.*711C>G | 3'UTR (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- SYT2 | c.*3347G>C | 3'UTR (SNP) | VAF 129/565 reads (23%) | called by muse, mutect2, varscan2
- TAP2 | c.*1325C>G | 3'UTR (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- TCTE1 | c.*642G>A | 3'UTR (SNP) | VAF 90/203 reads (44%) | called by muse, mutect2, varscan2
- TMEM129 | c.206-497C>A | Intron (SNP) | VAF 54/127 reads (43%) | called by muse, mutect2
- TMSB4X | c.-17+111G>A | Intron (SNP) | VAF 166/175 reads (95%) | called by muse, mutect2, varscan2
- TNFRSF1A | c.-135G>A | 5'UTR (SNP) | VAF 83/172 reads (48%) | catalogued as rs200370780; called by muse, mutect2, varscan2
- TRAPPC6B | c.*1419C>T | 3'UTR (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- TRIM67 | chr1:231218232 C>T | 3'Flank (SNP) | VAF 20/99 reads (20%) | catalogued as rs749172962; called by muse, mutect2, varscan2
- TSEN15 | c.*78C>T | 3'UTR (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- TTC22 | c.*398C>T | 3'UTR (SNP) | VAF 82/166 reads (49%) | catalogued as rs1278847534; called by muse, mutect2
- UBE2L3 | c.*161C>G | 3'UTR (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- UBR2 | c.-72G>A | 5'UTR (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- VAMP4 | c.*3511C>T | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- VKORC1 | c.*83G>A | 3'UTR (SNP) | VAF 116/225 reads (52%) | called by muse, mutect2, varscan2
- WIPI2 | c.740+46G>A | Intron (SNP) | VAF 75/152 reads (49%) | called by muse, mutect2, varscan2
- WLS | c.-138C>T | 5'UTR (SNP) | VAF 153/325 reads (47%) | called by muse, mutect2, varscan2
- WNK1 | c.2140-3283G>A | Intron (SNP) | VAF 41/87 reads (47%) | catalogued as rs1024009612, COSV60044432; called by muse, mutect2, varscan2
- YIF1A | c.642-20T>C | Intron (SNP) | VAF 73/144 reads (51%) | called by muse, mutect2, varscan2
- YTHDC1 | c.*118G>A | 3'UTR (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- YWHAQ | c.-82-21C>T | Intron (SNP) | VAF 84/191 reads (44%) | called by muse, mutect2, varscan2
- ZNF445 | c.-59G>T | 5'UTR (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- ZNF684 | c.-18G>A | 5'UTR (SNP) | VAF 45/105 reads (43%) | called by muse, mutect2, varscan2
- ZNF829 | c.-85+94G>A | Intron (SNP) | VAF 345/711 reads (49%) | catalogued as rs1285489832; called by muse, mutect2, varscan2
- ZSCAN2 | c.*1240_*1241del | 3'UTR (DEL) | VAF 4/43 reads (9%) | catalogued as rs1390161213; called by pindel, varscan2
